Surgical pathology report (de-identified scan), TCGA case TCGA-FG-6691, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-6691-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

SURGICAL PATHOLOGY REPORT

Addendum Present

Name
Accession #:
Date of Procedure:
Date Received:
Submitting Physician:

Med. Rec #.
Location:
Race:
DOB/Sex:

FINAL DIAGNOSIS

- A. RIGHT SUPERFICIAL TUMOR, BIOPSY:
-- FIBRILLARY ASTROCYTOMA (WHO GRADE II).
- B. RIGHT TEMPORAL LOBE OF BRAIN, LESION, BIOPSY:
-- FIBRILLARY ASTROCYTOMA (WHO GRADE II).
- C. SPECIMEN LABELED SUPERFICIAL TUMOR, BIOPSY:
-- FIBRILLARY ASTROCYTOMA (WHO GRADE II).
- D. SPECIMEN LABELED SUPERFICIAL TEMPORAL LOBE PART ONE, REMOVAL:
-- FIBRILLARY ASTROCYTOMA (WHO GRADE II) DEMONSTRATING PROMINENT MICROCYST FORMATION.
- E. SPECIAL LABELED INTERMEDIATE TUMOR LOBE, PART TWO, REMOVAL:
-- FIBRILLARY ASTROCYTOMA (WHO GRADE II) DEMONSTRATING PROMINENT MICROCYSTIC DEGENERATION.
- F. SPECIMEN LABELED DEEP POSTERIOR TUMOR PART THREE, REMOVAL:
-- FIBRILLARY ASTROCYTOMA (WHO GRADE II).
- G. SPECIMEN LABELED POSTERIOR INFERIOR TUMOR PART FOUR, REMOVAL:
-- FRAGMENTS OF HIPPOCAMPUS AND WHITE MATTER DEMONSTRATING MILD HYPERCELLULARITY, SUGGESTIVE OF INFILTRATING GLIOMA.
- H. TEMPORAL LOBE OF BRAIN, TUMOR, REMOVAL:
-- FIBRILLARY ASTROCYTOMA (WHO GRADE II).

Electronically Signed Out

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A: Microscopic and Touch Imprint: Low grade glioma. B,C: Touch imprint and microscopic: Glioma with features favoring high grade

Addendum/Procedures:

Addendum

Date Ordered:
Date Complete:
Date Reported:

Status: Signed Out

Fluorescence In Situ Hybridization, performed at the [REDACTED], demonstrates preservation of both chromosomes 1p and 19q. A copy of this report is on file in the Department of Pathology.

Electronically Signed Out By

[page 2 of 2]
Clinical History:

Right temporal brain lesion

Specimens Submitted As:

A:RIGHT SUPERFICIAL TUMOR
B:RIGHT TEMPORAL BRAIN LESION
C:SUPERIOR TUMOR
D:SUPERFICIAL TEMPORAL LOBE PT 1
E:INTERMEDIATE TEMPORAL LOBE PT 2
F:DEEP POSTERIOR TUMOR PT 3
G:POSTERIOR INFERIOR TUMOR PT 4
H:ASSCERTED TUMOR PT 9

Gross Description:

A: Received fresh for intraoperative consultation, labelled with the patient's name and number, are multiple, irregular fragments of pink-tan, soft tissue, 1.0 x 0.5 x 0.2 cm in aggregate. A portion of the specimen is submitted for touch imprint. A portion of the specimen is submitted for frozen section. The specimen is submitted entirely in two cassettes.

B: Received fresh for intraoperative consultation, labeled with patient's name, hospital number and "right temporal brain lesion", are multiple pink-white soft tissue fragments, 1.5 x 0.4 x 0.4 cm in aggregate. Representative tissue is submitted for touch imprint and frozen section. The remainder of the specimen is submitted entirely for permanent in 2 cassettes.

C: Received fresh for intraoperative consultation, labeled with patient's name, hospital number and "superior tumor", are multiple pink-white soft tissue fragments, 0.8 x 0.8 x 0.4 cm in aggregate. Representative tissue is submitted for touch imprint and frozen section. The remainder of the specimen is submitted entirely for permanent in 2 cassettes.

D: Received fresh, post fixed in formalin, labeled with patient's name, number, and "A superficial tumor R temp lobe", are two light tan to tan-gray irregular soft tissue fragments measuring 1.9 x 1.3 x 1.1 cm and 2.0 x 1.3 x 1.2 cm. On section, the fragments are tan-gray to focally red-brown. Submitted entirely in two cassettes.

E: Received fresh, post fixed in formalin, labeled with the patient's name, number, and "B-intermediate post of tumor", are three light tan to focally red-brown irregular soft tissue fragments measuring 1.5 x 1.3 x 0.7 cm, 1.9 x 1.0 x 0.9 cm, and 2.4 x 2.0 x 1.4 cm. On section, the fragments are light tan to tan-gray. Submitted entirely in three cassettes.

F: Received fresh, post fixed in formalin, labeled with the patient's name, number, and "C-deep/post tumor", are two tan-gray to focally red-brown irregular soft tissue fragments measuring 1.8 x 1.5 x 1.0 cm and 1.9 x 1.2 x 1.0 cm. On section, the fragments are tan-gray. Submitted entirely in two cassettes.

G: Received fresh, post fixed in formalin, labeled with the patient's name, number, and "D-post inf tumor", is one tan-gray irregular soft tissue fragment measuring 2.2 x 1.2 x 0.6 cm. On section, the fragment is tan-gray. Submitted entirely in one cassette.

H: Received fresh, post fixed in formalin, labeled with the patient's name, number, and "E-assc acd tumor for perm", are multiple tan-gray to focally red-brown irregular soft tissue fragments measuring 5.0 x 4.5 x 3.0 cm. On section, the fragments are tan-gray. A portion is given to [REDACTED]. Representative sections are submitted in three cassettes.

Summary of Cassettes:

A 1FS
2 remainder of specimen

Source: NCI Genomic Data Commons file aa883ef3-d057-41c2-bdda-f58ea3ebc7f1 (TCGA-FG-6691.799A7CC3-B435-4208-9996-F4360F80E5BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).